Surgical pathology report (de-identified scan), TCGA case TCGA-DI-A1C3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MD Anderson, specimen TCGA-DI-A1C3-01A (Primary Tumor).

[page 1 of 2]
Specimen Date/Time:

ICD - 0 - 3

Adenocarcinoma, Endometrioid, NOS 8380/3

Site Code: Endometrium C54.1

1/24/11

DIAGNOSIS

(A) OMENTUM, BIOPSY:

Adipose tissue with suture granulomas and adhesions. No tumor present.

(B) LEFT OVARY AND FALLOPIAN TUBE:

Fallopian tube, chronic inflammation.

Ovary, hemorrhagic cyst and multiple follicular cysts.

(C) UTERUS, CERVIX, GRADE AND DEPTH OF INVASION:

MULTIPLE FOCI OF ENDOMETRIAL ENDOMETRIOID ADENOCARCINOMA, FIGO GRADES 2 AND 1, ARISING IN A BACKGROUND OF EXTENSIVE COMPLEX ENDOMETRIAL HYPERPLASIA WITH ATYPIA.

SUPERFICIAL MYOMETRIAL INVASION PRESENT (3.0 MM IN DEPTH IN A 35.0 MM THICK MYOMETRIUM).

TUMOR EXTENDS INTO THE LOWER UTERINE SEGMENT AND INTO AREAS OF ADENOMYOSIS.

Complex endometrial hyperplasia with atypia extends into areas of adenomyosis.

No vascular/lymphatic invasion present.

Uterine cervix, no tumor present.

(D) ADDITIONAL OMENTUM:

Adipose tissue with adhesions, no tumor present.

GROSS DESCRIPTION

(A) OMENTUM BIOPSY - An irregular piece of unremarkable omentum (14.0 x 7.0 x 1.0 cm). Representative sections are submitted in A1-A7.

(B) LEFT OVARY AND FALLOPIAN TUBE - An ovary (8.3 x 5.6 x 4.2 cm) and attached fallopian tube (2.1 cm in length x 0.4 cm in diameter). Serial sectioning does not reveal any masses or nodules. There are hemorrhagic cysts and cystic follicles ranging in diameter from 0.4 to 1.1 cm.

SECTION CODE: B1-B5, hemorrhagic cyst for frozen section; B6-B10, additional sections of ovary; B11, representative sections of fallopian tube.

*FS/DX: REPRESENTATIVE SECTIONS SHOW OVARY WITH HEMORRHAGE, FOLLICULAR CYST, FALLOPIAN TUBE WITH INFLAMMATION.

(C) UTERUS, CERVIX, GRADE AND DEPTH OF INVASION - A uterus (13.0 x 11.0 x 5.5 cm) with smooth glistening serosal surface.

The endometrium contains a yellow-tan friable mass occupying the entire uterine cavity (16.0 x 6.5 cm), and extending to the anterior and posterior lower uterine segments. The lesion grossly does not invade into the cervix. Serial sectioning of the lesion revealed no definitive myometrium invasion. The myometrium ranges in thickness from 2.0 cm to 3.5 cm in depth.

INK CODE: Blue - anterior, black - posterior.

SECTION CODE: C1, C2, frozen section of anterior endometrium and myometrium full thickness; C3, frozen section of lesion in anterior lower uterine segment; C4, C5, frozen section of lesion in posterior endometrium and myometrium, full thickness; C6, frozen section of lesion in posterior lower uterine segment; C7-C23, lesion in anterior endometrium entirely submitted; C24, C25, lesion extending to the anterior lower uterine segment; C26-C47, lesion in posterior endometrium entirely submitted; C48, lesion extending to posterior lower uterine segment.

*FS/DX: REPRESENTATIVE SECTIONS SHOW MULTIFOCAL ENDOMETRIAL ENDOMETRIOID ADENOCARCINOMA, FIGO GRADE I, WITH SUPERFICIAL MYOMETRIAL INVASION AND EXTENSION TO THE LOWER UTERINE SEGMENT.

(D) ADDITIONAL OMENTUM - A single fragment of grossly unremarkable omental adipose tissue measuring (19.0 x 7.0 x 1.0

[page 2 of 2]
m). Representative sections are submitted in cassettes D1-D5.

CLINICAL HISTORY
none given

INOMED CODES

These tests have not been

Some tests reported here may have been developed and performance characteristics determined by
specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 58f21aab-639f-4e98-8f91-368b293b68db (TCGA-DI-A1C3.63A6706E-823B-456E-A3BC-65755C07CF62.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).